Somatic mutation profile of tumor specimen 0DUP1L from CCDI case PBCKUB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.3 years (1,921 days).
Specimen 0DUP1L: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf5f37a2-d408-40d1-a0f5-a057cce487f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUP1K (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5dfd85b-f514-4d35-b57d-bb78c4d8ea63

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: In Frame Del 1, 5'UTR 1, 3'UTR 1, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EFCAB2 | c.309_311del p.R104del (on ENST00000366522; = p.K5del on NM_032328.3) | In Frame Del (DEL) | VAF 46/123 reads (37%) | called by mutect2, varscan2
- ZNF225 | c.1670del p.M557Sfs*28 | Frame Shift Del (DEL) | VAF 155/418 reads (37%) | called by mutect2, varscan2
- SLC9A7 | c.1713C>T p.N571= | Silent (SNP) | VAF 203/493 reads (41%) | catalogued as rs763727030; called by muse, mutect2, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 18/582 reads (3%) | called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 16/180 reads (9%) | called by muse, varscan2
